Somatic mutation profile of tumor specimen TCGA-BD-A3ER-01A (aliquot TCGA-BD-A3ER-01A-11D-A20W-10) from TCGA case TCGA-BD-A3ER, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 62.0 years (22,657 days).
Specimen TCGA-BD-A3ER-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2877869-f0b9-476a-98b2-3cb6bc11da79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BD-A3ER-11A (Solid Tissue Normal), aliquot TCGA-BD-A3ER-11A-11D-A20W-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68cda8ac-7632-4dcd-9cc8-9126c2728ed0

The open-access MAF lists 60 somatic variants for this specimen: 44 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 15, Nonsense Mutation 6, Frame Shift Del 2, In Frame Del 1, Frame Shift Ins 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC127029.3 | c.557C>T p.T186I | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as COSV100033303; called by muse, mutect2, varscan2
- ADAMTS18 | c.3425G>A p.G1142E | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99272944; called by muse, mutect2, varscan2
- ASCC2 | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 31/133 reads (23%) | catalogued as COSV100316296; called by muse, mutect2, varscan2
- C3orf33 | c.229G>A p.V77I (on ENST00000340171 / NM_001308229.2; = p.V34I on NM_173657.2) | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.944); catalogued as COSV100420091; called by muse, mutect2, varscan2
- C9orf131 | c.2137G>T p.E713* | Nonsense Mutation (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100398126; called by muse, mutect2, varscan2
- CAMK1G | c.961C>T p.H321Y | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as rs747734197, COSV99151700; called by muse, mutect2, varscan2
- CCDC178 | c.1940G>T p.R647L (on ENST00000383096 / NM_001105528.3; = p.R609L on NM_198995.3) | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.093); catalogued as rs776180170, COSV100285056; called by muse, mutect2, varscan2
- COL5A1 | c.4288G>T p.A1430S | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs863223455, COSV100880027; called by muse, mutect2
- COPA | c.3248G>A p.R1083H | Missense Mutation (SNP) | VAF 49/247 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs141211632, COSV54099273; called by muse, mutect2, varscan2
- CORO7 | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 26/104 reads (25%) | catalogued as COSV99227710; called by muse, mutect2, varscan2
- EFCAB5 | c.2642G>A p.W881* | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as COSV100300283; called by muse, mutect2, varscan2
- EPG5 | c.1901C>T p.A634V | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.168); catalogued as COSV99957353; called by muse, mutect2, varscan2
- EPHA1 | c.1727A>T p.Q576L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99314048; called by muse, mutect2, varscan2
- EPS8 | c.2275A>G p.N759D | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV99843232; called by muse, mutect2, varscan2
- FMN1 | c.2364C>A p.C788* (on ENST00000616417 / NM_001277313.2; = p.C565* on NM_001103184.4) | Nonsense Mutation (SNP) | VAF 58/256 reads (23%) | catalogued as COSV100568753; called by muse, varscan2
- FN1 | c.2851G>A p.G951R | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.994); catalogued as rs772017194, COSV100116872, COSV100117259; called by muse, mutect2, varscan2
- GABRB2 | c.1337T>A p.L446* (on ENST00000274547; = p.L408* on NM_000813.3) | Nonsense Mutation (SNP) | VAF 39/135 reads (29%) | catalogued as COSV99196119; called by muse, mutect2
- GPRIN2 | c.503C>A p.A168D | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.153); catalogued as rs1292532523, COSV100966403; called by muse, mutect2, varscan2
- KIAA1522 | c.869C>A p.T290N (on ENST00000373480 / NM_001198972.2; = p.T349N on NM_020888.3) | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99614684; called by muse, mutect2, varscan2
- KRT2 | c.1910C>G p.S637C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV100548483; called by muse, mutect2, varscan2
- KRTAP27-1 | c.290G>T p.R97M | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101239727; called by muse, mutect2, varscan2
- LRRK2 | c.3346G>C p.G1116R | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100110317, COSV54168313; called by muse, mutect2, varscan2
- MICAL3 | c.1946C>T p.S649F | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99261723; called by muse, mutect2
- MROH8 | c.565G>A p.V189M | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1389981125, COSV99457355; called by muse, mutect2, varscan2
- NPAS3 | c.207T>G p.F69L (on ENST00000356141 / NM_001164749.2; = p.F39L on NM_022123.3) | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as COSV100388046; called by muse, mutect2
- NTRK1 | c.2371T>A p.Y791N | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100693421; called by muse, mutect2, varscan2
- OR52E6 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100259360; called by muse, mutect2
- PCLO | c.4684G>A p.E1562K | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV100433273, COSV61654306; called by muse, mutect2, varscan2
- PLA2G4A | c.1085T>G p.F362C | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100820561; called by muse, mutect2, varscan2
- SEMA3D | c.2249G>T p.W750L | Missense Mutation (SNP) | VAF 60/216 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.132); catalogued as COSV99406738; called by muse, mutect2, varscan2
- SI | c.2506G>A p.E836K | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.161); catalogued as COSV100015726; called by muse, mutect2, varscan2
- SLC12A8 | c.68C>A p.P23H | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.059); catalogued as COSV100102477; called by muse, mutect2, varscan2
- TENM3 | c.3466C>T p.R1156C | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1185466419, COSV69315982; called by muse, mutect2, varscan2
- TOB2 | c.523del p.T175Pfs*17 | Frame Shift Del (DEL) | VAF 21/79 reads (27%) | catalogued as COSV59500618; called by mutect2, pindel, varscan2
- TTN | c.58241C>A p.P19414Q (on ENST00000591111; = p.P11990Q on NM_003319.4) | Missense Mutation (SNP) | VAF 39/129 reads (30%) | PolyPhen probably damaging (0.919); catalogued as COSV100615548, COSV60011249; called by muse, mutect2, varscan2
- UBE3D | c.997A>G p.S333G | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.138); catalogued as COSV99388555; called by muse, mutect2, varscan2
- UBE4B | c.2305A>G p.I769V (on ENST00000343090 / NM_001105562.3; = p.I640V on NM_006048.5) | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.241); catalogued as rs761724316, COSV99476750; called by muse, mutect2, varscan2
- USP9Y | c.2131G>A p.D711N | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100168355; called by muse, mutect2
- ZC3H13 | c.56G>A p.S19N | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV54456259; called by muse, mutect2, varscan2
- CLTC | c.983_1022del p.C328Ffs*9 | Frame Shift Del (DEL) | VAF 12/92 reads (13%) | called by mutect2, pindel
- EPHA4 | c.2888dup p.N963Kfs*2 | Frame Shift Ins (INS) | VAF 31/146 reads (21%) | called by mutect2, pindel, varscan2
- FGD1 | c.1358T>C p.I453T | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- HNRNPLL | c.507_509del p.L171del | In Frame Del (DEL) | VAF 30/104 reads (29%) | called by pindel, varscan2
- OGDH | c.2632+2dup p.X878_splice | Splice Site (INS) | VAF 18/75 reads (24%) | called by mutect2, pindel, varscan2
- CCDC18 | c.2169C>T p.I723= (on ENST00000343253 / NM_001306076.1; = p.I724= on NM_206886.4) | Silent (SNP) | VAF 25/125 reads (20%) | catalogued as COSV100159625; called by muse, mutect2, varscan2
- DDX50 | c.2142A>G p.R714= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV65292453; called by muse, mutect2, varscan2
- DUSP23 | c.291G>A p.L97= | Silent (SNP) | VAF 7/141 reads (5%) | called by muse, mutect2
- DYSF | c.4440A>G p.K1480= | Silent (SNP) | VAF 36/155 reads (23%) | catalogued as CD116722, COSV99247499; called by muse, mutect2, varscan2
- IGKV2-24 | c.102C>T p.T34= | Silent (SNP) | VAF 88/345 reads (26%) | catalogued as rs755369433; called by muse, mutect2, varscan2
- OR4A15 | c.852C>A p.I284= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as COSV100124129; called by muse, mutect2, varscan2
- RNF213 | c.9288A>T p.T3096= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV100300666; called by muse, mutect2, varscan2
- RYR3 | c.84C>T p.T28= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs747585286, COSV101212875; called by muse, mutect2, varscan2
- SPAM1 | c.1059C>G p.L353= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs563527585, COSV99773085, COSV99773381; called by muse, mutect2, varscan2
- TRIM2 | c.426G>A p.T142= (on ENST00000437508; = p.T169= on NM_015271.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 31/104 reads (30%) | catalogued as rs945034696, COSV100107982; called by muse, mutect2, varscan2
- UBE3C | c.939T>C p.G313= | Silent (SNP) | VAF 39/143 reads (27%) | catalogued as COSV100779980; called by muse, mutect2, varscan2
- UNC13A | c.2241C>T p.D747= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as rs373430076; called by muse, mutect2, varscan2
- ZKSCAN4 | c.67C>T p.L23= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV66023360; called by muse, mutect2, varscan2
- ZKSCAN4 | c.66C>A p.L22= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV101043448; called by muse, mutect2, varscan2
- ZNF554 | c.1111C>T p.L371= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs1442164890, COSV100421213; called by muse, mutect2, varscan2
- PTPN6 | chr12:6964106 C>G | 3'Flank (SNP) | VAF 23/73 reads (32%) | called by muse, mutect2, varscan2
